Surgical pathology report (de-identified scan), TCGA case TCGA-15-1447, project TCGA-GBM (Glioblastoma Multiforme), tissue source site Mayo Clinic - Rochester, specimen TCGA-15-1447-01A (Primary Tumor).

Final Diagnosis:

Brain, bifrontal, excision No.2: Grade 4 (of 4) fibrillary astrocytoma, extensively infiltrating leptomeninges and dura, and forming a 4.3 x 3.9 x 2.8 cm mass.

Brain, right frontal lobe, biopsy (No. 1 and No. 2): Involved by grade 4 (of 4) fibrillary astrocytoma.

TCGA - 15 - 1447

Brain, left frontal cyst wall, biopsy: Involved by fibrillary astrocytoma.

Brain, left frontal lobe, biopsy: Benign brain parenchyma with isolated tumor cells.

Sinus, frontal, excision: Respiratory mucosa with mild chronic inflammation, negative for tumor.

Sinus, right ethmoid, left anterior ethmoid and left posterior ethmoid, biopsy: Respiratory mucosa with chronic inflammation, negative for tumor.

Seen in consultation with

Immunohistochemical stains were performed on paraffin-embedded tissue. Neoplastic cells stain with antibodies to GFAP and S-100 protein. Stains for neurofilament and synaptophysin are negative in neoplastic cells. Entrapped/infiltrated parenchyma is highlighted by the stains. Stains for cytokeratin (CAM 5.2, AE1/AE3) and chromogranin are negative. The findings support the above diagnosis.

Source: NCI Genomic Data Commons file 2f598e40-703a-486d-8d50-16c72a350035 (TCGA-15-1447.4E0B5741-45DB-4481-95EE-304C3648E673.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).